Somatic mutation profile of tumor specimen TCGA-49-4488-01A (aliquot TCGA-49-4488-01A-01D-1753-08) from TCGA case TCGA-49-4488, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 74.8 years (27,332 days).
Specimen TCGA-49-4488-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aa8f901-83be-4d62-9af9-957769a62493.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4488-11A (Solid Tissue Normal), aliquot TCGA-49-4488-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f13e461b-ed6d-4fdd-a360-70264d873f85

The open-access MAF lists 310 somatic variants for this specimen: 241 protein-altering or splice-affecting, 62 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 196, Silent 62, Nonsense Mutation 19, Splice Site 10, Frame Shift Del 9, Intron 4, Splice Region 4, Frame Shift Ins 2, RNA 2, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL7R | c.1184A>T p.K395M | Missense Mutation (SNP) | VAF 7/92 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen possibly damaging (0.618); catalogued as COSV57406142, COSV57406506, COSV57407763; called by muse, mutect2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 43/76 reads (57%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.8755C>T p.Q2919* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV71285149; called by muse, mutect2
- ABCA13 | c.13019A>G p.H4340R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68945030; called by muse, mutect2
- ABCA2 | c.3030G>T p.M1010I (on ENST00000614293; = p.M980I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55799552; called by muse, mutect2, varscan2
- ACSM5 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV59370368, COSV59370530; called by muse, mutect2, varscan2
- ADAMTS19 | c.2395A>T p.K799* | Nonsense Mutation (SNP) | VAF 42/121 reads (35%) | catalogued as COSV50738239; called by muse, mutect2, varscan2
- ADCY8 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); catalogued as COSV53902311, COSV53931446; called by muse, mutect2, varscan2
- ADIPOQ | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57858771; called by muse, mutect2, varscan2
- AHCTF1 | c.3742G>C p.A1248P (on ENST00000366508; = p.A1222P on NM_015446.5) | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV58247950; called by muse, mutect2, varscan2
- AMDHD1 | c.1194-1G>C p.X398_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV54117154, COSV99701299; called by muse, varscan2
- AMER1 | c.61C>A p.R21S | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV57657703, COSV57663971; called by muse, mutect2, varscan2
- ANK1 | c.5530C>T p.Q1844* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV55877674; called by muse, mutect2, varscan2
- AP2A1 | c.705G>T p.R235= | Splice Region (SNP) | VAF 7/10 reads (70%) | catalogued as rs911292473, COSV62817784; called by muse, mutect2, varscan2
- APOB | c.10973A>C p.H3658P | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV51929858; called by muse, mutect2, varscan2
- ARFGAP3 | c.1422C>G p.S474R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV54311239; called by muse, mutect2, varscan2
- ARPP21 | c.1557G>T p.Q519H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV51794771; called by muse, mutect2, varscan2
- ASB17 | c.378T>A p.S126R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV99407971; called by muse, mutect2, varscan2
- ASXL3 | c.4070C>A p.S1357Y | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52462022; called by muse, mutect2, varscan2
- ASZ1 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52912153; called by muse, mutect2
- ATP13A5 | c.1915+1G>C p.X639_splice | Splice Site (SNP) | VAF 5/98 reads (5%) | catalogued as COSV60867633; called by muse, mutect2
- BBOX1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs978954275, COSV54190208; called by muse, mutect2, varscan2
- BEGAIN | c.1274A>G p.D425G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62068385; called by muse, mutect2, varscan2
- BTBD3 | c.1293G>T p.Q431H | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.796); catalogued as COSV54778594; called by muse, mutect2, varscan2
- BTBD7 | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV58284558; called by muse, mutect2, varscan2
- BTG2 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51857200, COSV51858153; called by mutect2, varscan2
- C15orf39 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV62297666; called by muse, mutect2, varscan2
- C1orf94 | c.1154A>T p.K385I (on ENST00000488417 / NM_001134734.2; = p.K195I on NM_032884.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64913490; called by muse, mutect2, varscan2
- C2orf78 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68517005; called by muse, mutect2, varscan2
- C9 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV54675545; called by muse, mutect2, varscan2
- CACHD1 | c.3481A>G p.I1161V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.558); catalogued as COSV99262579; called by muse, mutect2, varscan2
- CCDC73 | c.1019A>G p.H340R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58796999; called by muse, mutect2
- CD5L | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 64/466 reads (14%) | catalogued as COSV63821511, COSV63821961; called by muse, mutect2, varscan2
- CENPH | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV51584594; called by muse, mutect2, varscan2
- CHST1 | c.1013del p.G338Afs*57 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | catalogued as rs1564995759; called by mutect2, pindel, varscan2
- CLEC12B | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); catalogued as COSV58863057; called by muse, mutect2, varscan2
- CLEC4F | c.804G>C p.R268S | Missense Mutation (SNP) | VAF 102/144 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as rs782108527, COSV55478807; called by muse, mutect2, varscan2
- CMAS | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57556324; called by muse, mutect2, varscan2
- COMMD10 | c.426C>A p.N142K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57235343; called by muse, mutect2, varscan2
- CP | c.717C>A p.Y239* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52829828; called by muse, mutect2, varscan2
- CPNE4 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV70192548; called by muse, mutect2, varscan2
- CSMD3 | c.5558C>A p.T1853N (on ENST00000297405 / NM_001363185.1; = p.T1749N on NM_052900.3) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV52140889; called by muse, mutect2, varscan2
- CTNND1 | c.2225G>T p.R742L (on ENST00000399050 / NM_001085458.2; = p.R736L on NM_001331.3) | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs201606412, COSV62382159; called by muse, mutect2, varscan2
- CTRC | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65621320; called by muse, mutect2, varscan2
- CYP11B1 | c.287A>C p.D96A | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV52825933; called by muse, mutect2
- DAOA | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV61601998; called by muse, mutect2, varscan2
- DCAF12L1 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64421445; called by muse, mutect2, varscan2
- DCAF12L1 | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV64421448; called by muse, mutect2, varscan2
- DCDC1 | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60838407; called by muse, varscan2
- DEFB116 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 179/363 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV68722001; called by muse, mutect2, varscan2
- DGKI | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55942137, COSV55943520, COSV55948114; called by muse, mutect2, varscan2
- DHX16 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV64563497; called by muse, mutect2, varscan2
- DIAPH3 | c.2350G>A p.E784K (on ENST00000400324 / NM_001042517.2; = p.E521K on NM_030932.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57367301; called by muse, mutect2, varscan2
- DNAH8 | c.10281T>G p.N3427K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV59435142; called by muse, mutect2, varscan2
- DPEP3 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV52050838; called by muse, mutect2, varscan2
- EIF2AK2 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV51795541, COSV51797283; called by muse, mutect2, varscan2
- ELMO1 | c.1654C>A p.R552S | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60300078, COSV60300321; called by muse, mutect2, varscan2
- ELOVL7 | c.74T>A p.V25D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV70917820, COSV70918100; called by muse, mutect2, varscan2
- ENPP3 | c.2107G>T p.D703Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV62953651; called by muse, mutect2, varscan2
- EP400 | c.6803A>G p.K2268R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57768326; called by muse, mutect2, varscan2
- EYA4 | c.804+1G>A p.X268_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV62049049; called by muse, mutect2, varscan2
- F11 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV53005254, COSV99251981; called by muse, mutect2, varscan2
- FAM47C | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV63724273; called by muse, mutect2, varscan2
- FASTKD3 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.366); catalogued as COSV52942579, COSV52944869; called by muse, mutect2
- FAT4 | c.10571G>T p.R3524L | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); catalogued as COSV58677801, COSV58686040; called by muse, mutect2, varscan2
- FBXL4 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV57745915; called by muse, mutect2, varscan2
- FBXO34 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100571996; called by muse, mutect2, varscan2
- FCGR3B | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54209390, COSV54209805; called by muse, mutect2, varscan2
- FLNA | c.2437G>A p.G813R | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs782276414, COSV61040435; called by muse, mutect2
- FMN2 | c.2932C>A p.P978T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.602); catalogued as COSV60425072; called by muse, mutect2, varscan2
- FXYD2 | c.26-1G>A p.X9_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99411437; called by muse, mutect2, varscan2
- G3BP2 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV62975985, COSV62976468; called by muse, mutect2, varscan2
- GDPD4 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1034560793, COSV60016915, COSV60018216; called by muse, mutect2, varscan2
- GIN1 | c.1295-2A>G p.X432_splice | Splice Site (SNP) | VAF 27/85 reads (32%) | catalogued as rs868986183, COSV101204347; called by muse, mutect2, varscan2
- GJB1 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960748, CM973163, COSV100661283; called by muse, mutect2
- GNPAT | c.1764G>C p.L588F | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV64153196; called by muse, mutect2
- GPC5 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65588136; called by muse, mutect2, varscan2
- GPR139 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58502305; called by muse, mutect2, varscan2
- GPR15 | c.1059G>T p.R353S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV52520145, COSV52520289; called by muse, mutect2, varscan2
- HAUS7 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs901316353, COSV57848278; called by muse, mutect2, varscan2
- HDAC4 | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV61862524, COSV61873113; called by muse, mutect2, varscan2
- HHIPL2 | c.1933A>T p.R645* | Nonsense Mutation (SNP) | VAF 41/236 reads (17%) | catalogued as COSV100596923; called by muse, mutect2, varscan2
- HUWE1 | c.8930C>A p.P2977H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53340116; called by muse, mutect2
- IFT88 | c.421G>C p.D141H (on ENST00000319980 / NM_001318493.2; = p.D132H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60672303; called by muse, mutect2
- IGSF22 | c.2537G>T p.W846L (on ENST00000319338; = p.W947L on NM_173588.4) | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55010357; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779866333, COSV56249099, COSV56306533; called by muse, mutect2, varscan2
- INPP4B | c.1839C>A p.S613R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV53717998; called by muse, mutect2, varscan2
- IQGAP2 | c.2309A>G p.Y770C | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57171198; called by muse, varscan2
- ITK | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV70061433; called by muse, mutect2, varscan2
- KATNIP | c.63+1G>T p.X21_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV55176877; called by muse, mutect2, varscan2
- KCNB2 | c.2009C>A p.A670D | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.026); catalogued as rs1293395628; called by muse, mutect2
- KCNJ3 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54534122; called by muse, mutect2, varscan2
- KEAP1 | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV50260840; called by muse, mutect2, varscan2
- KIF2B | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV52128836, COSV99276329; called by muse, mutect2, varscan2
- KLHL26 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56316750; called by mutect2, varscan2
- KRT33A | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 41/74 reads (55%) | catalogued as COSV50366021, COSV50366157; called by muse, mutect2, varscan2
- KSR2 | c.2786A>T p.E929V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56669389; called by muse, mutect2, varscan2
- KY | c.1248C>G p.I416M | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71016911, COSV71017231; called by muse, mutect2, varscan2
- LCT | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51543842, COSV51549787; called by muse, mutect2, varscan2
- LCT | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51465527; called by muse, mutect2, varscan2
- LDLRAD2 | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV60827894; called by muse, mutect2
- LHFPL1 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV64333180; called by muse, mutect2, varscan2
- LRP1B | c.8185G>A p.A2729T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs372667614, COSV101256084, COSV101257161, COSV67201434; called by muse, mutect2, varscan2
- LRP6 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV53785209; called by muse, mutect2, varscan2
- LTBP1 | c.1792C>A p.P598T (on ENST00000404816 / NM_206943.4; = p.P272T on NM_000627.4) | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774958490, COSV63183543; called by muse, mutect2, varscan2
- MAGEB1 | c.940A>G p.R314G | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100975024; called by muse, mutect2, varscan2
- MAGEB16 | c.467T>A p.L156Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.065); catalogued as COSV67873513, COSV67873748; called by muse, mutect2
- MAP1LC3B2 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs773841501, COSV61009934; called by muse, mutect2, varscan2
- MAP3K15 | c.3192C>A p.H1064Q | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV58827674; called by muse, mutect2, varscan2
- MAP3K20 | c.2203A>G p.R735G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV64377789; called by muse, mutect2, varscan2
- MED12 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV61335766; called by muse, mutect2, varscan2
- MEX3B | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as COSV61663104; called by muse, mutect2, varscan2
- MORC3 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV68688085; called by muse, mutect2, varscan2
- MRGPRE | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67746141; called by muse, mutect2, varscan2
- MUC16 | c.23483C>A p.S7828Y | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV67455901, COSV67480691; called by muse, mutect2, varscan2
- MUC16 | c.19514T>A p.V6505E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV67455909; called by muse, mutect2, varscan2
- MUC16 | c.2858G>T p.R953I | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV67455920; called by muse, mutect2, varscan2
- MXRA5 | c.5863T>C p.S1955P | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV54230071; called by muse, mutect2, varscan2
- MXRA5 | c.3583C>A p.Q1195K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54230100; called by muse, mutect2, varscan2
- MYEF2 | c.1691G>T p.C564F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV51046761; called by muse, mutect2, varscan2
- MYH15 | c.5366C>T p.A1789V | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs752209256, COSV56307183; called by muse, mutect2
- MYO16 | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs746964401, COSV62747930; called by muse, mutect2, varscan2
- NALCN | c.3163-2A>G p.X1055_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as COSV51926422; called by mutect2, varscan2
- NAV3 | c.2102C>A p.S701Y | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57071003; called by muse, mutect2, varscan2
- NAV3 | c.3902C>A p.A1301D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV57071022; called by muse, mutect2, varscan2
- NCKAP5 | c.5616C>A p.S1872R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV58430478, COSV58436460; called by muse, mutect2, varscan2
- NEGR1 | c.748G>T p.V250L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60838357; called by muse, mutect2, varscan2
- NF1 | c.2251G>T p.G751* | Nonsense Mutation (SNP) | VAF 72/120 reads (60%) | catalogued as CS076636, COSV100648504, COSV62198240, COSV62228997; called by muse, mutect2, varscan2
- NIBAN1 | c.2595G>T p.M865I | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV62284011; called by muse, mutect2, varscan2
- NLRC5 | c.5004G>T p.M1668I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV52652273; called by muse, varscan2
- NOTCH3 | c.3074C>A p.P1025H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as rs1401870864, COSV54630897, COSV54634871; called by muse, mutect2, varscan2
- NRDC | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.104); catalogued as COSV61403225; called by muse, mutect2, varscan2
- NRXN1 | c.3057C>A p.N1019K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58443757; called by muse, mutect2, varscan2
- NSUN6 | c.286T>A p.L96I | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV66032501; called by muse, mutect2, varscan2
- NTNG1 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53966746; called by muse, mutect2, varscan2
- NXF5 | n.840G>T | Splice Region (SNP) | VAF 59/190 reads (31%) | catalogued as COSV53790430; called by muse, mutect2, varscan2
- OR1C1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1324786719, COSV68715586; called by muse, mutect2, varscan2
- OR2A2 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV68871313; called by muse, mutect2, varscan2
- OR2AK2 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63550676; called by muse, mutect2, varscan2
- OR2G3 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60681249; called by muse, mutect2, varscan2
- OR2L13 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 82/366 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100813798; called by muse, varscan2
- OR2L8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs763873339, COSV61726091; called by muse, mutect2
- OR51D1 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62914032; called by muse, mutect2, varscan2
- OR5T1 | c.276A>T p.K92N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV100479090; called by muse, mutect2, varscan2
- OR8I2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV56167168; called by muse, mutect2, varscan2
- PARD3 | c.3772A>T p.R1258W | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61052305; called by muse, mutect2, varscan2
- PARD3B | c.228T>G p.I76M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV62506947; called by muse, mutect2, varscan2
- PCDHGA1 | c.893C>G p.T298R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV65295520, COSV65295808; called by muse, mutect2
- PCDHGA3 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1407685548, COSV53921539; called by muse, mutect2, varscan2
- PCLO | c.11254T>A p.C3752S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.306); catalogued as COSV61625022; called by muse, mutect2, varscan2
- PCMTD1 | c.60A>T p.E20D | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV100859705; called by muse, mutect2, varscan2
- PFKFB1 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | PolyPhen probably damaging (1); catalogued as COSV66628024; called by muse, mutect2, varscan2
- PLA2G2F | c.617C>A p.A206E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV64279877; called by muse, mutect2, varscan2
- PLA2G4C | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs780585013, COSV62784688, COSV62788580; called by muse, mutect2, varscan2
- PLK3 | c.844A>T p.S282C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV59499477; called by muse, mutect2, varscan2
- PLS3 | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56777318; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2089C>A p.R697S | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.165); catalogued as rs770821566, COSV99461428; called by muse, mutect2, varscan2
- PRKACB | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65762585; called by muse, mutect2, varscan2
- PRUNE2 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65039816; called by muse, mutect2, varscan2
- RAG1 | c.34A>C p.S12R | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV55024511; called by muse, mutect2
- RBM19 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV55689836; called by muse, mutect2
- RCE1 | c.883T>C p.F295L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100547121; called by muse, varscan2
- RGS7 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 47/261 reads (18%) | catalogued as COSV58535665; called by muse, mutect2, varscan2
- RNF20 | c.628+1G>C p.X210_splice | Splice Site (SNP) | VAF 26/57 reads (46%) | catalogued as COSV66355597; called by muse, mutect2, varscan2
- RTCB | c.928A>C p.M310L | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53277848; called by muse, mutect2, varscan2
- RYR1 | c.2185G>T p.V729L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62093438; called by muse, mutect2, varscan2
- RYR2 | c.9437T>A p.I3146N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV63675345; called by muse, mutect2, varscan2
- SCN10A | c.2114C>A p.T705N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV71860846; called by muse, mutect2, varscan2
- SEC61G | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV100769264; called by muse, mutect2, varscan2
- SEMA6C | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766594931, COSV59001420; called by muse, mutect2
- SIGLEC1 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV52461038, COSV52464084; called by muse, mutect2, varscan2
- SIGLEC9 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51583389; called by muse, mutect2, varscan2
- SLC11A1 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 59/570 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51916344, COSV99262478; called by muse, mutect2, varscan2
- SLC17A6 | c.754T>C p.F252L | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV54134873; called by muse, mutect2
- SLC1A6 | c.1362C>T p.I454= | Splice Region (SNP) | VAF 32/52 reads (62%) | catalogued as COSV55669249, COSV55674870; called by muse, mutect2, varscan2
- SLC36A2 | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as COSV58862748; called by muse, mutect2, varscan2
- SLC4A3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.102); catalogued as COSV56092629; called by muse, mutect2, varscan2
- SLC9C2 | c.1700G>A p.S567N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV62944779; called by muse, mutect2, varscan2
- SPACA3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/24 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52190833; called by muse, mutect2, varscan2
- SPTA1 | c.4446G>A p.W1482* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as COSV63751049; called by muse, mutect2, varscan2
- SPTAN1 | c.1845G>T p.Q615H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV63986133; called by muse, mutect2
- TAAR9 | c.332T>G p.F111C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.029); catalogued as COSV71512207; called by muse, mutect2, varscan2
- TAT | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63532544, COSV63533047; called by muse, mutect2, varscan2
- TBX15 | c.1786C>T p.Q596* (on ENST00000369429 / NM_001330677.2; = p.Q490* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV52869357; called by muse, mutect2, varscan2
- TEX15 | c.5409C>A p.C1803* (on ENST00000256246; = p.C2186* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV56344066; called by muse, mutect2, varscan2
- TGM4 | c.1759C>A p.P587T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99942408; called by muse, mutect2, varscan2
- TGM4 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942412; called by muse, mutect2, varscan2
- TMEM145 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV56624561; called by muse, mutect2, varscan2
- TMEM255A | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV59028555, COSV59030330; called by muse, mutect2, varscan2
- TNFRSF11A | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54022637, COSV99500105; called by muse, mutect2, varscan2
- TNN | c.2384C>A p.T795K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53423890; called by muse, mutect2, varscan2
- TPTE | c.871G>T p.D291Y (on ENST00000618007 / NM_199261.4; = p.D273Y on NM_199259.4) | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs373367615; called by muse, mutect2, varscan2
- TRERF1 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV61669203; called by muse, mutect2, varscan2
- TRIM58 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773381876, COSV63569634; called by muse, mutect2
- TRIML1 | c.1015G>T p.G339W | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60193806; called by muse, mutect2, varscan2
- TSHR | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.832); catalogued as COSV99992128; called by muse, mutect2, varscan2
- TTC37 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62454260; called by muse, mutect2, varscan2
- TTC6 | c.271G>T p.D91Y (on ENST00000267368; = p.D1360Y on NM_001310135.3) | Missense Mutation (SNP) | VAF 224/431 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV99941963; called by muse, mutect2, varscan2
- TTN | c.70000G>C p.E23334Q (on ENST00000591111; = p.E15910Q on NM_003319.4) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | PolyPhen probably damaging (0.997); catalogued as COSV59964484; called by muse, mutect2
- TTN | c.20416G>T p.G6806W (on ENST00000591111; = p.G5879W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV59964525; called by muse, mutect2, varscan2
- UBA7 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs192842960, COSV61091727; called by muse, mutect2
- UBE3B | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55092243; called by muse, mutect2, varscan2
- UGT1A6 | c.512T>A p.F171Y | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV59385653; called by muse, mutect2, varscan2
- UGT2B15 | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57733718, COSV57734263; called by muse, mutect2, varscan2
- UMODL1 | c.3776-1G>T p.X1259_splice (on ENST00000408910 / NM_001004416.2; = p.X1387_splice on NM_173568.3) | Splice Site (SNP) | VAF 77/212 reads (36%) | catalogued as COSV68569520; called by muse, mutect2, varscan2
- UNC79 | c.6834T>A p.D2278E (on ENST00000393151 / NM_001346218.2; = p.D2101E on NM_020818.5) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV56381037; called by muse, mutect2, varscan2
- USH2A | c.13886A>C p.E4629A | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56341385, COSV56349247; called by muse, mutect2, varscan2
- USH2A | c.3409G>T p.V1137L | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100237189; called by muse, mutect2, varscan2
- VARS1 | c.2348-1G>T p.X783_splice | Splice Site (SNP) | VAF 40/114 reads (35%) | catalogued as COSV63304382; called by muse, mutect2, varscan2
- VEGFC | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV54595965; called by muse, mutect2, varscan2
- WDR91 | c.1813G>T p.G605W | Missense Mutation (SNP) | VAF 93/170 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60369156; called by muse, mutect2, varscan2
- WNK3 | c.5189C>T p.P1730L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); catalogued as COSV100671598; called by muse, mutect2, varscan2
- WNK3 | c.5188C>A p.P1730T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.417); catalogued as COSV63612196, COSV63615165; called by muse, mutect2, varscan2
- XAGE5 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100657828, COSV63567636; called by muse, mutect2, varscan2
- XG | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66985493; called by muse, mutect2, varscan2
- XRCC5 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV67535531; called by muse, mutect2, varscan2
- ZAP70 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV53853388; called by muse, mutect2
- ZBBX | c.1733A>T p.Q578L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV56785952; called by muse, mutect2
- ZFHX4 | c.10747C>A p.Q3583K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50650855; called by muse, mutect2, varscan2
- ZFP91 | c.1705G>T p.G569* | Nonsense Mutation (SNP) | VAF 77/136 reads (57%) | catalogued as COSV60158143; called by muse, mutect2, varscan2
- ZMYM4 | c.3166G>T p.E1056* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100111342, COSV58908560; called by muse, mutect2, varscan2
- ZNF117 | c.1256G>T p.C419F | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99275789; called by muse, mutect2, varscan2
- ZNF285 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV58408462; called by muse, mutect2, varscan2
- ZNF423 | c.3460C>A p.L1154I (on ENST00000563137 / NM_001379286.1; = p.L1146I on NM_015069.4) | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV52183201; called by muse, mutect2, varscan2
- ZNF572 | c.965A>T p.H322L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60001523; called by muse, mutect2, varscan2
- ZNF71 | c.1177G>T p.G393W | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV60147194; called by muse, mutect2, varscan2
- ZPBP | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV50423721; called by muse, mutect2, varscan2
- ZSCAN4 | c.614T>A p.V205E | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.202); catalogued as COSV56591966; called by muse, mutect2, varscan2
- AKR1C2 | c.528_529del p.L177Qfs*40 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- BANK1 | c.842del p.P281Qfs*75 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- CPB1 | c.367del p.E123Kfs*3 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- DDX52 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FBXO2 | c.423dup p.G142Wfs*22 | Frame Shift Ins (INS) | VAF 19/151 reads (13%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.404); called by muse, mutect2
- KIR2DL3 | c.472T>A p.Y158N | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMB1 | c.4756dup p.T1586Nfs*4 | Frame Shift Ins (INS) | VAF 66/152 reads (43%) | called by mutect2, pindel, varscan2
- LRP1B | c.13364del p.T4455Ifs*2 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- NLRP3 | c.2120del p.P707Qfs*13 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.878del p.G293Efs*19 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | called by mutect2, varscan2
- SYT9 | c.1440del p.I481Lfs*15 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- UBR4 | c.6390del p.K2130Nfs*41 | Frame Shift Del (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel, varscan2
- ACOT9 | c.925C>A p.R309= | Silent (SNP) | VAF 49/167 reads (29%) | catalogued as COSV60537226; called by muse, mutect2, varscan2
- ADAMTSL1 | c.357T>C p.C119= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV52812851; called by muse, mutect2, varscan2
- ANK2 | c.5754C>A p.P1918= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV52153544; called by muse, mutect2, varscan2
- ANKRD30A | c.1425G>A p.E475= (on ENST00000611781; = p.E419= on NM_052997.2) | Silent (SNP) | VAF 73/118 reads (62%) | catalogued as COSV64607578, COSV64611635; called by muse, mutect2, varscan2
- C12orf50 | c.735A>T p.L245= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV53894357; called by muse, mutect2, varscan2
- CCKBR | c.534G>T p.T178= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV58100005; called by muse, mutect2, varscan2
- CD180 | c.48C>A p.A16= | Silent (SNP) | VAF 119/185 reads (64%) | catalogued as rs146337741; called by muse, mutect2, varscan2
- CENPB | c.1083C>T p.L361= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100713488, COSV100713580; called by muse, mutect2
- CNTNAP5 | c.18G>T p.R6= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV70480016; called by muse, mutect2, varscan2
- CTNND2 | c.1338G>A p.P446= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs780920780, COSV58876426; called by mutect2, varscan2
- CXorf56 | c.393C>A p.T131= (on ENST00000536133 / NM_001170570.2; = p.T145= on NM_022101.4) | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV57437935; called by muse, mutect2, varscan2
- EYS | c.147C>A p.I49= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV60981072; called by muse, mutect2, varscan2
- FASLG | c.810G>A p.E270= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV60679956; called by muse, mutect2, varscan2
- FGD4 | c.219G>A p.Q73= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV56782216; called by muse, mutect2, varscan2
- GABRR3 | c.486C>T p.I162= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV72084046; called by muse, mutect2, varscan2
- GALNT14 | c.393C>A p.I131= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV61103794; called by muse, mutect2, varscan2
- GJA10 | c.1449G>A p.Q483= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV65354982; called by muse, mutect2, varscan2
- GRIA3 | c.894C>A p.A298= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV52054409; called by muse, mutect2, varscan2
- HHIPL2 | c.1551G>T p.L517= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV58564198; called by muse, mutect2, varscan2
- INSC | c.1032T>A p.A344= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV65409696; called by muse, mutect2, varscan2
- KCNH8 | c.2088C>T p.P696= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV60459702; called by muse, mutect2, varscan2
- KRTAP4-3 | c.396C>A p.P132= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV101194163; called by muse, mutect2, varscan2
- LAMA1 | c.184C>A p.R62= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV67531455, COSV67534406; called by muse, mutect2, varscan2
- LRRC31 | c.777G>A p.L259= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV52980183; called by muse, mutect2, varscan2
- MAB21L2 | c.84C>A p.A28= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100462221; called by muse, mutect2, varscan2
- MCC | c.369G>T p.L123= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV68726767; called by muse, mutect2, varscan2
- MEP1A | c.2148C>A p.G716= | Silent (SNP) | VAF 30/187 reads (16%) | catalogued as COSV57919148; called by muse, mutect2, varscan2
- MLH3 | c.1218G>A p.L406= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV53134730; called by muse, mutect2, varscan2
- MYH2 | c.1956A>C p.T652= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV55434751; called by muse, varscan2
- NGDN | c.201G>A p.L67= | Silent (SNP) | VAF 10/203 reads (5%) | catalogued as COSV68142154; called by muse, mutect2
- OR2L8 | c.489C>T p.L163= | Silent (SNP) | VAF 20/189 reads (11%) | catalogued as COSV61726342; called by muse, mutect2, varscan2
- OR4C15 | c.591G>A p.L197= (on ENST00000314644; = p.L143= on NM_001001920.2) | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs1404239577, COSV58951916; called by muse, mutect2, varscan2
- OSR2 | c.204C>A p.T68= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV52556154; called by muse, mutect2, varscan2
- PCNX2 | c.5970G>A p.S1990= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs372086633; called by muse, mutect2, varscan2
- PGK2 | c.286C>T p.L96= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as COSV59163359; called by muse, varscan2
- PLP1 | c.384C>A p.G128= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as COSV58275753, COSV58275981; called by muse, mutect2, varscan2
- PNLIPRP3 | c.264C>A p.I88= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV65047466; called by muse, mutect2, varscan2
- PRAMEF10 | c.663G>T p.T221= | Silent (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- PRKCH | c.756C>T p.N252= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV60647056; called by muse, mutect2, varscan2
- PROK2 | c.114C>A p.S38= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV55208595; called by muse, mutect2, varscan2
- PROM2 | c.360G>T p.V120= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58297484; called by muse, mutect2, varscan2
- PROSER1 | c.2622G>T p.P874= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV61486879; called by muse, mutect2, varscan2
- PTGER4 | c.111G>T p.V37= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV56720450; called by muse, mutect2, varscan2
- PTX4 | c.435C>A p.A145= (on ENST00000447419 / NM_001328608.2; = p.A140= on NM_001013658.1) | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV53515072; called by muse, mutect2, varscan2
- RECQL5 | c.1473C>T p.S491= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1214964775, COSV58638738; called by muse, mutect2, varscan2
- RGN | c.444C>T p.D148= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100282459; called by muse, mutect2, varscan2
- RPS6KL1 | c.171C>A p.I57= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV63580901; called by muse, mutect2, varscan2
- SLC22A16 | c.831G>T p.V277= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57928590; called by muse, mutect2, varscan2
- SLITRK3 | c.948T>A p.S316= | Silent (SNP) | VAF 51/161 reads (32%) | catalogued as COSV53846829; called by muse, mutect2, varscan2
- SPATA31A3 | c.3681C>A p.R1227= | Silent (SNP) | VAF 22/48 reads (46%) | called by mutect2, varscan2
- SPTA1 | c.699C>A p.P233= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV63751052; called by muse, mutect2, varscan2
- SRPX | c.516C>A p.A172= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2
- STK10 | c.693C>G p.A231= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV51572567; called by muse, mutect2, varscan2
- TECRL | c.687T>C p.S229= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV67086329; called by muse, mutect2, varscan2
- TENM1 | c.2826C>T p.S942= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs376967455, COSV64428588; called by muse, mutect2, varscan2
- TRAV8-4 | c.315G>T p.A105= | Silent (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- TRPA1 | c.1050T>A p.T350= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV51558449; called by muse, mutect2, varscan2
- TUBB8 | c.939G>T p.A313= | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as rs782168299, COSV59114665, COSV59115148; called by muse, mutect2, varscan2
- UGT2B4 | c.81G>T p.L27= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV100522641, COSV59316195, COSV59319988; called by muse, mutect2, varscan2
- UNC5C | c.2508C>A p.V836= | Silent (SNP) | VAF 65/225 reads (29%) | catalogued as COSV71658875; called by muse, mutect2, varscan2
- ZNF385D | c.63T>A p.R21= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV55750526; called by muse, mutect2, varscan2
- ZXDA | c.306C>A p.T102= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV62387756; called by muse, mutect2, varscan2
- GBA3 | c.59-8114A>T | Intron (SNP) | VAF 55/111 reads (50%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16486C>G | Intron (SNP) | VAF 17/61 reads (28%) | catalogued as COSV64953459; called by muse, mutect2, varscan2
- JAK1 | c.-162+8154C>G | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- LY9 | c.454+1777G>T | Intron (SNP) | VAF 100/228 reads (44%) | catalogued as COSV54437922, COSV99626928; called by muse, varscan2
- MIR557 | n.85T>C | RNA (SNP) | VAF 88/210 reads (42%) | called by muse, mutect2, varscan2
- SLC37A3 | c.*61T>A | 3'UTR (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100405559; called by muse, mutect2, varscan2
- WASF4P | n.193G>T | RNA (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
